Somatic mutation profile of tumor specimen 0DJILU from CCDI case PBBXDM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,502 days).
Specimen 0DJILU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cd6e0a8-4632-4a1f-a2c3-245ece8ccb65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJIKY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/813655a2-7565-4154-a77b-efd18a483209

The open-access MAF lists 30 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Intron 2, Nonstop Mutation 1, RNA 1, 3'UTR 1, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 293/1543 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 508/589 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 424/542 reads (78%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs375557460; called by muse, mutect2, varscan2
- FBLN2 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1186720660; called by muse, mutect2, varscan2
- HCRTR2 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 342/874 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV100904170; called by muse, mutect2, varscan2
- OR14C36 | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 264/1035 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs534789808, COSV58602676; called by muse, mutect2, varscan2
- OR4C6 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 108/1270 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.03); catalogued as COSV100051439; called by muse, mutect2
- AC004922.1 | c.2054G>C p.*685Sext*5 | Nonstop Mutation (SNP) | VAF 268/901 reads (30%) | called by muse, mutect2, varscan2
- CIC | c.4052C>A p.S1351* | Nonsense Mutation (SNP) | VAF 70/397 reads (18%) | called by muse, mutect2, varscan2
- EIF2AK4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 463/1175 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- HSPA4L | c.1742A>C p.D581A | Missense Mutation (SNP) | VAF 28/1112 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- NIN | c.540A>C p.Q180H | Missense Mutation (SNP) | VAF 190/898 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- OLIG2 | c.335del p.K112Rfs*58 | Frame Shift Del (DEL) | VAF 256/606 reads (42%) | called by mutect2, varscan2
- PSG1 | c.805T>G p.Y269D | Missense Mutation (SNP) | VAF 167/761 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- RESF1 | c.3881G>T p.R1294I | Missense Mutation (SNP) | VAF 933/1744 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SNX29 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 291/358 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACTN2 | c.1132C>T p.L378= | Silent (SNP) | VAF 397/1971 reads (20%) | called by muse, mutect2, varscan2
- BCLAF1 | c.780G>A p.Q260= | Silent (SNP) | VAF 161/746 reads (22%) | catalogued as rs764455588; called by muse, mutect2, varscan2
- GPD1L | c.318G>A p.E106= | Silent (SNP) | VAF 96/1014 reads (9%) | called by muse, mutect2
- NRIP1 | c.1983A>G p.K661= | Silent (SNP) | VAF 62/1478 reads (4%) | catalogued as COSV100011998; called by muse, mutect2
- NTRK2 | c.888C>G p.T296= | Silent (SNP) | VAF 277/1561 reads (18%) | called by muse, mutect2, varscan2
- OCRL | c.21C>T p.V7= | Silent (SNP) | VAF 355/840 reads (42%) | called by muse, mutect2, varscan2
- SLC47A1 | c.600C>T p.L200= | Silent (SNP) | VAF 493/601 reads (82%) | catalogued as rs372578108; called by muse, mutect2, varscan2
- SRSF4 | c.237C>T p.Y79= | Silent (SNP) | VAF 141/1122 reads (13%) | catalogued as rs771063725; called by muse, mutect2, varscan2
- STYK1 | c.1006C>T p.L336= | Silent (SNP) | VAF 450/1382 reads (33%) | catalogued as COSV99311896; called by muse, mutect2, varscan2
- AC084816.1 | n.1046T>A | RNA (SNP) | VAF 9/52 reads (17%) | called by mutect2, varscan2
- FIG4 | c.1434+21C>T | Intron (SNP) | VAF 359/776 reads (46%) | catalogued as rs75463717; called by muse, mutect2, varscan2
- FOXP1 | c.181-18006A>C | Intron (SNP) | VAF 102/760 reads (13%) | called by muse, mutect2, varscan2
- SEC14L2 | c.-92C>T | 5'UTR (SNP) | VAF 18/56 reads (32%) | called by mutect2, varscan2
- SV2B | c.*80T>C | 3'UTR (SNP) | VAF 75/264 reads (28%) | called by muse, mutect2, varscan2
